CCDI case PBBVLZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/be29e0d7-49d4-45db-b853-b5a692e8ff52

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.7 years (3,169 days).

Biospecimens (2 samples)
- Sample 0DIFII: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIFIX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
